Somatic mutation profile of tumor specimen MBCProject_6876_T1_WES (aliquot MBCProject_6876_T1_WES_1) from CMI case MBCProject_6876, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 61.7 years (22,533 days).
Specimen MBCProject_6876_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8ee2bc9c-655c-44cd-976a-b27141777482.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_6876_SALIVA (Saliva), aliquot MBCProject_6876_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/26585f47-d717-488e-981b-c58961db02cb

The open-access MAF lists 60 somatic variants for this specimen: 40 protein-altering or splice-affecting, 9 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 9, Intron 5, Nonsense Mutation 4, 3'UTR 2, 5'UTR 2, RNA 1, 3'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC2 | c.3503C>T p.S1168L | Missense Mutation (SNP) | VAF 35/148 reads (24%) | SIFT tolerated (0.47); PolyPhen benign (0.226); catalogued as COSV100966361, COSV100966669; called by muse, mutect2, varscan2
- ADCY5 | c.203G>A p.R68H | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs776480737; called by muse, mutect2, varscan2
- CNTN2 | c.1277G>A p.R426H | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs143340514; ClinVar: uncertain significance; called by muse, varscan2
- CYLC1 | c.1414G>T p.D472Y | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.785); catalogued as COSV61414108; called by muse, mutect2, varscan2
- DPYD | c.1547C>A p.S516Y | Missense Mutation (SNP) | VAF 146/326 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.496); catalogued as rs769514867; called by muse, mutect2, varscan2
- FAM189A1 | c.894C>A p.Y298* | Nonsense Mutation (SNP) | VAF 24/65 reads (37%) | catalogued as COSV54294511; called by muse, mutect2, varscan2
- JPH2 | c.470C>T p.S157L | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); catalogued as rs772526418, COSV65902531; called by muse, mutect2, varscan2
- KIAA0319L | c.3103G>A p.G1035R | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769064246; called by muse, mutect2, varscan2
- KNL1 | c.528G>C p.Q176H (on ENST00000346991 / NM_170589.5; = p.Q150H on NM_144508.5) | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.051); catalogued as rs1290664364; called by muse, varscan2
- KNL1 | c.592G>A p.E198K (on ENST00000346991 / NM_170589.5; = p.E172K on NM_144508.5) | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.436); catalogued as COSV61156429; called by muse, varscan2
- KNL1 | c.3733G>A p.V1245I (on ENST00000346991 / NM_170589.5; = p.V1219I on NM_144508.5) | Missense Mutation (SNP) | VAF 55/122 reads (45%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs1391686161; called by muse, mutect2, varscan2
- NGF | c.248G>A p.R83H | Missense Mutation (SNP) | VAF 78/298 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs767272925, COSV65687880; called by muse, mutect2, varscan2
- NLRC3 | c.49G>A p.G17S | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs1388548019; called by muse, mutect2, varscan2
- OR8B12 | c.775C>T p.L259F | Missense Mutation (SNP) | VAF 33/147 reads (22%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.993); catalogued as COSV100172937; called by muse, mutect2, varscan2
- OTUD6A | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 28/126 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.227); catalogued as rs1465157091, COSV57973338; called by muse, mutect2, varscan2
- PRKD1 | c.2242G>A p.A748T | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs1303923680, COSV100119516, COSV59576052; called by muse, mutect2, varscan2
- RAG2 | c.1517G>A p.R506H | Missense Mutation (SNP) | VAF 79/387 reads (20%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs144812762; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RYR2 | c.6380G>T p.R2127L | Missense Mutation (SNP) | VAF 37/240 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM1313841, COSV63669324, COSV63693748; called by muse, mutect2, varscan2
- SESN2 | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.059); catalogued as COSV99455474; called by muse, mutect2, varscan2
- TENM2 | c.6646G>A p.V2216I (on ENST00000518659 / NM_001122679.2; = p.V1977I on NM_001080428.3) | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.76); PolyPhen benign (0.229); catalogued as rs1419780807, COSV69123331; called by muse, mutect2, varscan2
- TM2D3 | c.437C>T p.T146M (on ENST00000333202 / NM_078474.3; = p.T120M on NM_025141.3) | Missense Mutation (SNP) | VAF 65/419 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as rs764016225; called by muse, mutect2, varscan2
- TP53 | c.466del p.R156Afs*14 | Frame Shift Del (DEL) | VAF 53/112 reads (47%) | catalogued as CD156964, COSV52711846, COSV52730924, COSV53119766; called by mutect2, pindel, varscan2
- BRSK1 | c.1057C>A p.L353M | Missense Mutation (SNP) | VAF 60/308 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.893); called by muse, varscan2
- CCAR2 | c.2649C>A p.S883R | Missense Mutation (SNP) | VAF 18/148 reads (12%) | SIFT tolerated (0.42); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CCAR2 | c.2650C>T p.Q884* | Nonsense Mutation (SNP) | VAF 18/149 reads (12%) | called by muse, mutect2, varscan2
- CHIC2 | c.80C>T p.P27L | Missense Mutation (SNP) | VAF 73/125 reads (58%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAH2 | c.6950T>C p.F2317S | Missense Mutation (SNP) | VAF 44/84 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ECI1 | c.431C>G p.S144C | Missense Mutation (SNP) | VAF 72/196 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- ECPAS | c.1613G>C p.R538T | Missense Mutation (SNP) | VAF 41/130 reads (32%) | SIFT tolerated (0.59); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GALNT13 | c.1075C>G p.H359D | Missense Mutation (SNP) | VAF 32/186 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, varscan2
- KNL1 | c.1800G>C p.L600F (on ENST00000346991 / NM_170589.5; = p.L574F on NM_144508.5) | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- KNL1 | c.1957G>A p.D653N (on ENST00000346991 / NM_170589.5; = p.D627N on NM_144508.5) | Missense Mutation (SNP) | VAF 79/200 reads (40%) | SIFT tolerated (0.94); PolyPhen benign (0); called by muse, mutect2, varscan2
- KNL1 | c.4864G>A p.D1622N (on ENST00000346991 / NM_170589.5; = p.D1596N on NM_144508.5) | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.76); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MCFD2 | c.336G>C p.M112I | Missense Mutation (SNP) | VAF 56/253 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- NIPSNAP3B | c.454C>G p.Q152E | Missense Mutation (SNP) | VAF 33/120 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- PAXBP1 | c.1088C>G p.S363* | Nonsense Mutation (SNP) | VAF 138/428 reads (32%) | called by muse, varscan2
- SMARCAD1 | c.1355G>C p.R452T | Missense Mutation (SNP) | VAF 57/95 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TBXT | c.133G>A p.G45S | Missense Mutation (SNP) | VAF 28/137 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- USO1 | c.1781C>G p.S594C | Missense Mutation (SNP) | VAF 51/86 reads (59%) | SIFT tolerated (0.13); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- XPO1 | c.2860G>T p.E954* | Nonsense Mutation (SNP) | VAF 18/85 reads (21%) | called by muse, varscan2
- CNTRL | c.5340G>A p.S1780= | Silent (SNP) | VAF 99/327 reads (30%) | catalogued as rs144649433; called by muse, mutect2, varscan2
- COL6A2 | c.2748C>T p.H916= | Silent (SNP) | VAF 35/189 reads (19%) | catalogued as rs372206114; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DYNC1H1 | c.13182G>A p.T4394= | Silent (SNP) | VAF 32/97 reads (33%) | catalogued as rs754395575; called by muse, mutect2, varscan2
- FIGN | c.297G>A p.V99= | Silent (SNP) | VAF 98/213 reads (46%) | called by muse, mutect2, varscan2
- KNL1 | c.1668G>A p.G556= (on ENST00000346991 / NM_170589.5; = p.G530= on NM_144508.5) | Silent (SNP) | VAF 43/126 reads (34%) | called by muse, mutect2, varscan2
- MAPK6 | c.2088A>T p.T696= | Silent (SNP) | VAF 15/178 reads (8%) | called by muse, mutect2
- MFN1 | c.1014A>G p.E338= | Silent (SNP) | VAF 102/197 reads (52%) | called by muse, mutect2, varscan2
- TRIP10 | c.1785C>T p.Y595= (on ENST00000313244 / NM_001288962.2; = p.Y539= on NM_004240.4) | Silent (SNP) | VAF 13/74 reads (18%) | catalogued as rs1385665253; called by muse, mutect2, varscan2
- ZCCHC18 | c.1005G>T p.G335= | Silent (SNP) | VAF 34/219 reads (16%) | catalogued as COSV62458429; called by muse, mutect2, varscan2
- AK9 | c.3633+13_3633+15del | Intron (DEL) | VAF 8/41 reads (20%) | catalogued as rs201441562; called by pindel, varscan2
- ASPG | chr14:104117456 C>T | 3'Flank (SNP) | VAF 12/48 reads (25%) | called by muse, mutect2, varscan2
- CCNQP1 | n.345G>T | RNA (SNP) | VAF 58/268 reads (22%) | called by muse, mutect2, varscan2
- IGFN1 | c.1241+2870G>A | Intron (SNP) | VAF 163/397 reads (41%) | catalogued as rs555917404; called by muse, mutect2, varscan2
- NOP58 | c.122+1258A>G | Intron (SNP) | VAF 12/43 reads (28%) | called by muse, mutect2, varscan2
- P4HTM | c.1073+39G>C | Intron (SNP) | VAF 75/152 reads (49%) | called by muse, mutect2, varscan2
- PLA2G4C | c.-12C>T | 5'UTR (SNP) | VAF 27/104 reads (26%) | called by muse, mutect2, varscan2
- SEPTIN10 | c.1349+519G>T | Intron (SNP) | VAF 111/241 reads (46%) | called by muse, mutect2, varscan2
- SFT2D2 | c.*4253G>T | 3'UTR (SNP) | VAF 42/416 reads (10%) | catalogued as COSV99608044; called by muse, mutect2
- TBC1D32 | c.*381T>C | 3'UTR (SNP) | VAF 8/29 reads (28%) | called by muse, mutect2
- TIMM10B | c.-4C>T | 5'UTR (SNP) | VAF 22/197 reads (11%) | catalogued as rs760987713; called by muse, mutect2, varscan2
